Somatic mutation profile of tumor specimen MP2PRT-PAMLHU-TMP1-A (aliquot MP2PRT-PAMLHU-TMP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PAMLHU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.7 years (2,802 days).
Specimen MP2PRT-PAMLHU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 668b0e61-b795-4c08-8fa0-99396dd85562.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAMLHU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAMLHU-NB1-A-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e272b669-c5cf-4d3c-940d-ecaa085f2fc4

The open-access MAF lists 23 somatic variants for this specimen: 15 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 7, Frame Shift Ins 1, Frame Shift Del 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4336C>T p.R1446C | Missense Mutation (SNP) | VAF 106/232 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398124146, COSV52113365, COSV52115600, COSV52116725; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 54/137 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs1057519725, COSV55498939; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- DCX | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 193/843 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as COSV57568703; called by muse, mutect2, varscan2
- INSYN1 | c.833C>T p.T278M | Missense Mutation (SNP) | VAF 108/242 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779716412, COSV65838122; called by muse, mutect2
- KCNU1 | c.1786G>A p.V596I | Missense Mutation (SNP) | VAF 60/122 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.716); catalogued as rs767440917; called by muse, mutect2, varscan2
- SBNO2 | c.1149C>T p.V383= | Splice Region (SNP) | VAF 30/294 reads (10%) | catalogued as rs751819625; called by muse, mutect2, varscan2
- SVEP1 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 139/320 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as rs750793434; called by muse, varscan2
- WDR59 | c.2126C>T p.P709L | Missense Mutation (SNP) | VAF 125/247 reads (51%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV50934371; called by muse, mutect2, varscan2
- BAG2 | c.361G>A p.V121I | Missense Mutation (SNP) | VAF 131/459 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- EIF2S3 | c.35A>T p.Q12L | Missense Mutation (SNP) | VAF 156/804 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- GOLGA8F | c.665A>T p.D222V (on ENST00000526619; = p.D428V on NM_001350920.2) | Missense Mutation (SNP) | VAF 73/311 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- GUCY2F | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 158/642 reads (25%) | SIFT tolerated (0.88); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- KMT2A | c.3994_4006del p.P1332Nfs*20 | Frame Shift Del (DEL) | VAF 84/240 reads (35%) | called by pindel, varscan2*
- SLC34A2 | c.1100T>A p.I367N | Missense Mutation (SNP) | VAF 118/408 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAF3 | c.251_252insC p.H85Sfs*4 | Frame Shift Ins (INS) | VAF 112/277 reads (40%) | called by mutect2, pindel, varscan2
- AR | c.2679G>A p.P893= | Silent (SNP) | VAF 240/977 reads (25%) | catalogued as rs371057180, COSV101017725; called by muse, mutect2, varscan2
- BBS5 | c.18G>A p.A6= | Silent (SNP) | VAF 104/253 reads (41%) | catalogued as COSV99752222; called by muse, mutect2, varscan2
- DDIT4 | c.153C>T p.S51= | Silent (SNP) | VAF 171/434 reads (39%) | catalogued as rs760955954; called by muse, mutect2, varscan2
- FOXS1 | c.651G>A p.A217= | Silent (SNP) | VAF 163/335 reads (49%) | catalogued as rs1215500141, COSV54066060; called by muse, mutect2, varscan2
- GPR183 | c.300A>C p.G100= | Silent (SNP) | VAF 94/221 reads (43%) | called by muse, mutect2, varscan2
- RGS7 | c.885G>C p.P295= | Silent (SNP) | VAF 71/188 reads (38%) | called by muse, mutect2, varscan2
- TTC6 | c.2232G>A p.A744= | Silent (SNP) | VAF 57/196 reads (29%) | catalogued as rs748404929; called by muse, mutect2, varscan2
- CACNA1G | c.4422+208G>A | Intron (SNP) | VAF 115/356 reads (32%) | catalogued as rs199892912; called by muse, varscan2
